TCGA case TCGA-44-8117 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6d96a298-be5a-4e14-afe8-ca4b6ca298d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.4 years (19,855 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 113 days; Days to treatment end: 176 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 113 days; Days to treatment end: 133 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 259 days; Disease response: Tumor Free.
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 86; FEV1/FVC after bronchodilator (%): 88; FEV1/FVC before bronchodilator (%): 83; FEV1 after bronchodilator (% of reference): 65; FEV1 before bronchodilator (% of reference): 60.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 54; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 2011.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-8117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-44-8117-01A-01-BS1: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 0; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-44-8117-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-44-8117-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-8117-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1; Shortest dimension: 0.7.
  Slide TCGA-44-8117-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 385 days; disease-specific survival: no event (censored), 385 days; disease-free interval: no event (censored), 385 days; progression-free interval: no event (censored), 385 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-8117-01A-11D-2237-01): tumor purity 0.66, ploidy 2.89, whole-genome doublings 1.
